Gene-level copy-number profile of tumor specimen CDDP-ACK4-TTP1-A from CDDP_EAGLE case CDDP-ACK4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71 years.
Specimen CDDP-ACK4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 514230da-0f48-4aa2-89c5-0e5c3df813e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACK4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,272 have no estimate.
https://portal.gdc.cancer.gov/files/87243afa-d3ef-4886-9de7-9e5d9a4e3cc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,008; copy number 2: 53,506; copy number 3: 3,390; copy number 4: 247; copy number 5: 142; copy number 6: 29; copy number 7: 8; copy number 8: 6; copy number 9: 13; copy number 16: 1; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 200 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,295,503–154,297,748, 2 genes, copy number 5: RNU6-239P, RNU6-121P.
- chr5:196,868–693,352, 22 genes, copy number 5: CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:2,921,496–4,147,429, 10 genes, copy number 5–6: AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr7:74,773,962–74,789,376, 1 gene, copy number 9: NCF1.
- chr7:75,156,639–75,395,434, 13 genes, copy number 9–35 (within-gene range 3–35): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, AC211486.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2.
- chr12:64,599,078–64,609,459, 1 gene, copy number 5: AC078962.4.
- chr15:21,951,242–21,951,323, 1 gene, copy number 16: MIR5701-3.
- chr15:43,599,563–43,618,800, 1 gene, copy number 6 (within-gene range 2–6): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 6 (within-gene range 3–6): AC011330.3.
- chr16:58,092,053–58,092,947, 1 gene, copy number 5: AC012182.1.
- chr20:50,190,830–50,192,668, 1 gene, copy number 5 (within-gene range 2–5): CEBPB.
- chr20:53,668,697–53,875,557, 3 genes, copy number 5–6: RNU7-14P, AC006076.1, SUMO1P1.
- chr20:58,389,229–58,619,888, 4 genes, copy number 5: VAPB, APCDD1L, APCDD1L-DT, AL050327.1.
- chr20:58,740,532–59,516,039, 26 genes, copy number 5: PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.
- chr20:60,055,853–61,940,617, 13 genes, copy number 5–7 (within-gene range 4–7): C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1.
- chr20:61,432,868–62,700,480, 42 genes, copy number 5–7: AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686.
- chr20:63,502,287–63,698,684, 12 genes, copy number 5–8 (within-gene range 4–8): AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B.
- chr20:63,707,465–64,327,972, 43 genes, copy number 5–8 (within-gene range 4–8): ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
